Gene-level copy-number profile of tumor specimen TCGA-49-AAR0-01A from TCGA case TCGA-49-AAR0, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.3 years (20,932 days).
Specimen TCGA-49-AAR0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.fa210e9d-40de-444c-9087-d36d1a174d1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-AAR0-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9409a685-e54e-4a6c-ab68-2834a34b33a5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,311; copy number 3: 30,580; copy number 4: 23,288; copy number 5: 2,172; copy number 6: 319; copy number 7: 54; copy number 10: 10; copy number 15: 24; copy number 17: 40; copy number 21: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-AAR0-01A-21D-A396-01): tumor purity 0.51, ploidy 1.63, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 149 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,683,978–42,142,620, 21 genes, copy number 21: TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132.
- chr12:14,973,042–17,711,046, 36 genes, copy number 7–10: PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA.
- chr12:57,253,762–57,818,704, 40 genes, copy number 17 (within-gene range 6–17): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P.
- chr12:58,544,124–61,232,937, 23 genes, copy number 7 (within-gene range 6–7): AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1.
- chr14:62,069,518–62,152,258, 5 genes, copy number 7: AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3.
- chr15:89,950,760–90,314,499, 24 genes, copy number 15 (within-gene range 3–15): AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
